CCDI case PBBPNS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/4555f3ce-f1fb-4a68-8cdd-816d48102292

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 18.3 years (6,694 days).

Biospecimens (3 samples)
- Sample 0DE5NC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE5ON: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE5R0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
